Somatic mutation profile of tumor specimen TCGA-24-1464-01A (aliquot TCGA-24-1464-01A-01W-0549-09) from TCGA case TCGA-24-1464, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.8 years (25,874 days).
Specimen TCGA-24-1464-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccbec9f1-d459-49ca-8982-d1d6cb23f8d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1464-10A (Blood Derived Normal), aliquot TCGA-24-1464-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adf8aa69-0b92-45ff-abb7-6f2fea2a9124

The open-access MAF lists 62 somatic variants for this specimen: 46 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Nonsense Mutation 5, Frame Shift Ins 3, Splice Site 2, Frame Shift Del 1, RNA 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 73/126 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs1057519999, COSV52661127, COSV52664176, COSV52966384; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARID4B | c.3305A>G p.N1102S | Missense Mutation (SNP) | VAF 95/292 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0.018); catalogued as COSV51599031; called by muse, mutect2, varscan2
- BCAS3 | c.2432A>T p.D811V (on ENST00000390652 / NM_001353144.2; = p.D796V on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/98 reads (87%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.601); catalogued as COSV66770515; called by muse, mutect2, varscan2
- BECN1 | c.1214A>G p.D405G | Missense Mutation (SNP) | VAF 236/292 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59311706; called by muse, mutect2
- CAMK4 | c.436A>G p.K146E | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV56663529; called by muse, mutect2, varscan2
- CCDC141 | c.3080A>T p.D1027V | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55369604; called by muse, mutect2, varscan2
- CDC42BPB | c.2484G>T p.E828D | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100775363; called by muse, mutect2
- CERCAM | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100863943; called by muse, mutect2, varscan2
- CNTN5 | c.1615C>G p.L539V | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.096); catalogued as COSV54285526; called by muse, mutect2, varscan2
- CSMD3 | c.4416G>C p.W1472C (on ENST00000297405 / NM_001363185.1; = p.W1368C on NM_052900.3) | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52113461, COSV52161014; called by muse, mutect2, varscan2
- DCAF5 | c.2786C>A p.T929K | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV100432377; called by muse, mutect2
- FERMT3 | c.1624C>T p.R542C (on ENST00000279227 / NM_178443.3; = p.R538C on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs760475221, COSV54177371; called by muse, mutect2, varscan2
- GAN | c.218T>C p.I73T | Missense Mutation (SNP) | VAF 104/157 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377294873; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HABP2 | c.654G>T p.W218C | Missense Mutation (SNP) | VAF 16/524 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100667897; called by muse, mutect2
- HOXC4 | c.220G>C p.G74R | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV57698007; called by muse, varscan2
- HSD17B2 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 260/336 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV52274548; called by muse, mutect2, varscan2
- JCAD | c.1729G>T p.E577* | Nonsense Mutation (SNP) | VAF 121/362 reads (33%) | catalogued as COSV64758200, COSV64761588; called by muse, mutect2, varscan2
- KIF5B | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV56651127; called by muse, mutect2, varscan2
- KMO | c.1174T>G p.S392A | Missense Mutation (SNP) | VAF 81/314 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as COSV59362766; called by muse, mutect2, varscan2
- MAK | c.848A>G p.Y283C | Missense Mutation (SNP) | VAF 88/353 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100504362; called by muse, mutect2, varscan2
- MAML2 | c.1540A>G p.M514V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV73262853; called by muse, mutect2, varscan2
- MSH5 | c.812+1G>T p.X271_splice | Splice Site (SNP) | VAF 48/292 reads (16%) | catalogued as COSV65208602; called by muse, mutect2, varscan2
- MSH6 | c.3132C>G p.Y1044* | Nonsense Mutation (SNP) | VAF 98/305 reads (32%) | catalogued as COSV52275191; called by muse, mutect2, varscan2
- NHLRC2 | c.2094G>A p.M698I | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV65174439; called by muse, mutect2, varscan2
- NOTCH4 | c.5672dup p.G1892Rfs*24 | Frame Shift Ins (INS) | VAF 10/79 reads (13%) | catalogued as rs777647776; called by mutect2, varscan2
- OR4C16 | c.256A>T p.K86* | Nonsense Mutation (SNP) | VAF 128/363 reads (35%) | catalogued as COSV58940928; called by muse, mutect2, varscan2
- PCDHB1 | c.1733C>G p.P578R | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239629939, COSV100128128; called by muse, mutect2, varscan2
- PDS5B | c.2997G>T p.L999F | Missense Mutation (SNP) | VAF 65/103 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59724081; called by muse, mutect2, varscan2
- PHF20L1 | c.721G>T p.G241* | Nonsense Mutation (SNP) | VAF 178/323 reads (55%) | catalogued as COSV55189461; called by muse, mutect2, varscan2
- PKHD1 | c.7589C>G p.S2530C | Missense Mutation (SNP) | VAF 6/186 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100582522; called by muse, mutect2
- PSMC4 | c.435dup p.E146Rfs*97 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | catalogued as rs747871663; called by pindel, varscan2
- RIOK1 | c.1577A>G p.D526G | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV53571421; called by muse, mutect2, varscan2
- SMC1A | c.2684G>A p.R895H | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59127669; called by muse, mutect2, varscan2
- SNX25 | c.1696-1G>A p.X566_splice | Splice Site (SNP) | VAF 126/299 reads (42%) | catalogued as COSV53011987; called by muse, mutect2, varscan2
- SPIDR | c.2668G>C p.V890L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV52380748, COSV99854774; called by muse, mutect2, varscan2
- THOP1 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs748495490, COSV57017863; called by muse, mutect2, varscan2
- TUBA1C | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.024); catalogued as rs763427275, COSV99988739; called by muse, mutect2, varscan2
- TUBA4A | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 86/282 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.079); catalogued as rs1375554152, COSV50277748; called by muse, mutect2, varscan2
- VAC14 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as rs1382669923, COSV55751379; called by muse, mutect2, varscan2
- VARS2 | c.2482G>A p.V828M | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs765928958, COSV58911459; called by muse, mutect2, varscan2
- VPS52 | c.1790C>G p.T597R | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV71403405; called by muse, mutect2, varscan2
- WBP11 | c.788A>G p.D263G | Missense Mutation (SNP) | VAF 233/569 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53761927; called by muse, mutect2, varscan2
- ZNF706 | c.123C>A p.C41* | Nonsense Mutation (SNP) | VAF 106/287 reads (37%) | catalogued as COSV60862956; called by muse, mutect2, varscan2
- MINK1 | c.3757dup p.E1253Gfs*19 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- NPR1 | c.1625_1628del p.S542Cfs*2 | Frame Shift Del (DEL) | VAF 82/243 reads (34%) | called by mutect2, pindel, varscan2
- PRRC2A | c.4423G>T p.G1475C | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACTL8 | c.1095G>A p.R365= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV64860325; called by muse, mutect2, varscan2
- CDX1 | c.486C>T p.T162= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as rs753003920, COSV51567566; called by muse, mutect2, varscan2
- COMMD10 | c.330C>T p.V110= | Silent (SNP) | VAF 77/187 reads (41%) | catalogued as COSV57234232; called by muse, mutect2, varscan2
- DMD | c.1833A>G p.E611= | Silent (SNP) | VAF 31/49 reads (63%) | catalogued as COSV55856409; called by muse, mutect2, varscan2
- FHL2 | c.223C>T p.L75= | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as COSV59078678, COSV59078884; called by muse, mutect2, varscan2
- GCN1 | c.3060C>T p.P1020= | Silent (SNP) | VAF 31/43 reads (72%) | catalogued as COSV56104456; called by muse, mutect2, varscan2
- IVNS1ABP | c.1800G>C p.G600= | Silent (SNP) | VAF 195/501 reads (39%) | catalogued as COSV62250624; called by muse, mutect2, varscan2
- LRRC17 | c.894C>T p.N298= | Silent (SNP) | VAF 87/243 reads (36%) | catalogued as rs1004001192, COSV50864121; called by muse, mutect2, varscan2
- NEB | c.14685T>C p.D4895= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs974199168, COSV50826941; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEXMIF | c.66G>A p.G22= | Silent (SNP) | VAF 57/105 reads (54%) | catalogued as COSV50022498, COSV50022581; called by muse, mutect2, varscan2
- OR10Q1 | c.426C>T p.R142= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV57469838; called by muse, mutect2, varscan2
- SAMD9L | c.3702A>C p.G1234= | Silent (SNP) | VAF 14/564 reads (2%) | catalogued as COSV100560592; called by muse, mutect2
- TTN | c.25359C>T p.F8453= (on ENST00000591111; = p.F7526= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as COSV59909842; called by muse, mutect2, varscan2
- ACP4 | chr19:50798377 C>T | 3'Flank (SNP) | VAF 16/53 reads (30%) | catalogued as COSV54516279; called by muse, mutect2, varscan2
- C11orf40 | n.156T>C | RNA (SNP) | VAF 61/158 reads (39%) | catalogued as rs763669764, COSV56889988; called by muse, mutect2, varscan2
- UBE2C | c.217-75_217-57del | Intron (DEL) | VAF 153/300 reads (51%) | called by mutect2, pindel, varscan2
